Somatic mutation profile of tumor specimen TCGA-38-4630-01A (aliquot TCGA-38-4630-01A-01D-1265-08) from TCGA case TCGA-38-4630, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-38-4630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef0a4a4f-60a3-4ea4-b836-0547026d32c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4630-11A (Solid Tissue Normal), aliquot TCGA-38-4630-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2e630bf-b7a4-4f1c-af45-21183089137f

The open-access MAF lists 132 somatic variants for this specimen: 96 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 34, Nonsense Mutation 11, Splice Site 3, In Frame Del 3, Intron 2, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 36/60 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAD9 | c.891G>C p.M297I | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58309108; called by muse, mutect2, varscan2
- ACSL3 | c.836C>G p.S279* | Nonsense Mutation (SNP) | VAF 83/207 reads (40%) | catalogued as COSV62483940; called by muse, mutect2, varscan2
- ACSS1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV60223104; called by muse, mutect2, varscan2
- ADRB2 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); catalogued as COSV60005970; called by muse, mutect2, varscan2
- AHNAK2 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.76); catalogued as COSV60923846, COSV60928638; called by muse, mutect2, varscan2
- AMDHD2 | c.825del p.A276Pfs*43 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | catalogued as COSV53550515; called by pindel, varscan2
- ANKHD1-EIF4EBP3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51852354, COSV51854240; called by muse, varscan2
- ARFGEF3 | c.6229C>T p.R2077W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373666994; called by muse, mutect2, varscan2
- ARHGAP27 | c.1445G>A p.W482* (on ENST00000428638 / NM_001282290.1; = p.W141* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as COSV65358309; called by muse, mutect2, varscan2
- ATF4 | c.376dup p.L126Pfs*6 | Frame Shift Ins (INS) | VAF 114/489 reads (23%) | catalogued as rs1278387390; called by mutect2, pindel, varscan2
- BIRC6 | c.8130G>C p.W2710C | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70203553; called by muse, mutect2, varscan2
- C7orf33 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as rs752681436, COSV61023626, COSV61023860; called by muse, mutect2, varscan2
- CAPRIN1 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV58221398; called by muse, mutect2, varscan2
- CAVIN2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs373902541; called by muse, mutect2, varscan2
- CCNT2 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99751220; called by muse, mutect2, varscan2
- CD109 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV54653850; called by muse, mutect2, varscan2
- CD163 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.345); catalogued as rs956253157, COSV63135649; called by muse, mutect2, varscan2
- CEACAM3 | c.549C>G p.S183R | Missense Mutation (SNP) | VAF 27/1016 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99705120; called by muse, mutect2
- DBN1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV52791575; called by muse, mutect2, varscan2
- DKK4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs758663008, COSV55182568; called by muse, mutect2, varscan2
- DUSP6 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54379218, COSV54379286; called by muse, mutect2, varscan2
- EDEM1 | c.1581C>G p.V527= | Splice Region (SNP) | VAF 151/228 reads (66%) | catalogued as COSV56583450, COSV99849031; called by muse, mutect2, varscan2
- ENPP3 | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.222); catalogued as COSV62955535; called by muse, mutect2
- EXOC3L1 | c.1098G>C p.E366D | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV52047884; called by muse, mutect2, varscan2
- FAM217B | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV100674670; called by muse, varscan2
- FARP1 | c.2434-1G>A p.X812_splice | Splice Site (SNP) | VAF 27/732 reads (4%) | catalogued as rs1383256719, COSV60343606; called by muse, mutect2
- FAT4 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.208); catalogued as COSV67894854; called by muse, mutect2, varscan2
- FNDC3A | c.766G>C p.D256H (on ENST00000492622 / NM_001079673.2; = p.D200H on NM_014923.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs768845610, COSV65696199; called by muse, mutect2, varscan2
- FOXK2 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58881529; called by muse, mutect2, varscan2
- GGN | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.052); catalogued as COSV53058081; called by muse, mutect2, varscan2
- GPR139 | c.173G>T p.R58I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV58504104; called by muse, mutect2, varscan2
- GRK3 | c.2059G>T p.G687C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60798946; called by muse, mutect2, varscan2
- GTSF1 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59939157; called by muse, mutect2, varscan2
- HELZ | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62379909; called by muse, mutect2, varscan2
- KANK4 | c.1841A>T p.Y614F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV62988227; called by muse, mutect2, varscan2
- KHDC4 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100850856; called by muse, mutect2, varscan2
- KLHL10 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV53174207; called by muse, mutect2, varscan2
- KLHL9 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757171; called by muse, mutect2, varscan2
- LATS2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs754388230, COSV66878215; called by muse, varscan2
- LPL | c.421T>C p.W141R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60932269; called by muse, mutect2, varscan2
- LRRC8A | c.2160C>T p.I720= | Splice Region (SNP) | VAF 80/150 reads (53%) | catalogued as rs759781334, COSV52188139; ClinVar: likely benign; called by muse, varscan2
- MEI1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV55905558; called by muse, mutect2, varscan2
- MFN2 | c.1436C>G p.S479C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV99337090; called by muse, mutect2, varscan2
- MIA2 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54485275; called by muse, mutect2
- MKKS | c.79T>G p.S27A | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1336191814, COSV61399391; called by muse, mutect2, varscan2
- MRGPRX4 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1385546799, COSV100049849; called by muse, varscan2
- MST1R | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as rs983490364, COSV56571915; called by muse, mutect2, varscan2
- NEUROD4 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as COSV54472788, COSV54472910; called by muse, mutect2, varscan2
- NFATC4 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372741212; called by muse, mutect2, varscan2
- NLGN4X | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763852947, COSV52015376; called by muse, mutect2, varscan2
- NNMT | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55474484; called by muse, mutect2, varscan2
- NT5C2 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV58415808; called by muse, mutect2, varscan2
- OPCML | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59438940; called by muse, mutect2, varscan2
- OR10G9 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs745618594, COSV66686586; called by mutect2, varscan2
- OR11H1 | c.765C>A p.C255* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as COSV99422020; called by mutect2, varscan2
- OR2J2 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV65847997, COSV65848230; called by muse, varscan2
- PARP15 | c.1573-1G>A p.X525_splice (on ENST00000464300 / NM_001113523.3; = p.X291_splice on NM_152615.2) | Splice Site (SNP) | VAF 30/109 reads (28%) | catalogued as COSV59974065; called by muse, mutect2, varscan2
- PCDH17 | c.3389G>C p.R1130T | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as COSV64976992; called by muse, mutect2, varscan2
- PCDHA1 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV65372765; called by muse, mutect2, varscan2
- PGAP6 | c.1635G>C p.R545S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV51741231; called by muse, mutect2, varscan2
- PRAMEF4 | c.1126C>A p.L376M | Missense Mutation (SNP) | VAF 125/443 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765823906, COSV52440455; called by mutect2, varscan2
- RASAL1 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55658357; called by muse, mutect2, varscan2
- RFFL | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52073199, COSV52074645; called by muse, mutect2, varscan2
- RFPL1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs371158882, COSV62978332; called by muse, mutect2, varscan2
- RIMS2 | c.3675A>T p.R1225S | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51705407; called by muse, mutect2, varscan2
- RNF103 | c.1193A>C p.N398T | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV52896251; called by muse, mutect2, varscan2
- ROPN1L | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs762533473, COSV99928784; called by muse, mutect2, varscan2
- RRBP1 | c.2417G>T p.R806L (on ENST00000377813 / NM_001365613.2; = p.R373L on NM_004587.3) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55705075; called by mutect2, varscan2
- RYR2 | c.11746G>T p.V3916F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV63688638, COSV63702103; called by muse, mutect2, varscan2
- SELENOT | c.537T>A p.N179K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV71982298; called by muse, mutect2, varscan2
- SLC9A9 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs767428360, COSV57238078; called by muse, mutect2, varscan2
- SLITRK3 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53851368, COSV53852427; called by muse, mutect2, varscan2
- SMAD1 | c.776-1G>C p.X259_splice | Splice Site (SNP) | VAF 87/265 reads (33%) | catalogued as COSV100129787, COSV57472668, COSV57472877; called by muse, mutect2, varscan2
- STIP1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54182072; called by muse, mutect2, varscan2
- STOX1 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as COSV53812869; called by muse, mutect2, varscan2
- STOX1 | c.1626C>G p.I542M | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV53816702; called by muse, mutect2, varscan2
- TACC3 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 47/374 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV57559793; called by muse, mutect2, varscan2
- TACC3 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 73/317 reads (23%) | catalogued as COSV57606740; called by muse, mutect2, varscan2
- TBC1D5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV53765276, COSV99509074; called by muse, mutect2, varscan2
- TBX15 | c.589T>A p.Y197N (on ENST00000369429 / NM_001330677.2; = p.Y91N on NM_152380.3) | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874319; called by muse, mutect2
- TOP3A | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58179799; called by muse, mutect2, varscan2
- TSR1 | c.1898C>G p.T633S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs202215567, COSV56786275; called by muse, mutect2, varscan2
- USP9X | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV61072902; called by muse, mutect2, varscan2
- WDR70 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54279466; called by muse, mutect2, varscan2
- XIRP2 | c.2356G>A p.D786N (on ENST00000628543; = p.D961N on NM_152381.6) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as COSV54720755; called by muse, mutect2, varscan2
- ZNF197 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as rs760841561, COSV60359947; called by muse, mutect2, varscan2
- ZNF556 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 30/55 reads (55%) | catalogued as rs139842259; called by muse, mutect2, varscan2
- ZNF804B | c.1747T>G p.Y583D | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60828364; called by muse, mutect2, varscan2
- ZYG11B | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53755408; called by muse, mutect2, varscan2
- DIO2 | c.104_105insTTGA p.K35Nfs*2 | Nonsense Mutation (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- FAM120A | c.2818_2823del p.I940_P941del | In Frame Del (DEL) | VAF 33/79 reads (42%) | called by mutect2, pindel, varscan2
- IPO8 | c.1398_1400del p.L467del | In Frame Del (DEL) | VAF 36/104 reads (35%) | called by pindel, varscan2
- LPO | c.1997_1999del p.F666del | In Frame Del (DEL) | VAF 52/157 reads (33%) | called by mutect2, pindel, varscan2
- THAP12 | c.1966dup p.I656Nfs*9 | Frame Shift Ins (INS) | VAF 52/187 reads (28%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- AHNAK2 | c.2835G>C p.L945= | Silent (SNP) | VAF 149/638 reads (23%) | catalogued as COSV60911548; called by muse, mutect2, varscan2
- ARX | c.132G>T p.L44= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV66875649; called by muse, mutect2, varscan2
- ATP8B3 | c.1158C>T p.F386= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as rs1288001207, COSV59546094; called by muse, mutect2, varscan2
- C10orf90 | c.2022C>T p.I674= | Silent (SNP) | VAF 78/253 reads (31%) | catalogued as COSV52960221; called by muse, mutect2, varscan2
- C1orf115 | c.369C>T p.F123= | Silent (SNP) | VAF 72/218 reads (33%) | catalogued as rs775578543, COSV54273764; called by muse, varscan2
- CABIN1 | c.966C>A p.I322= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV54086447; called by muse, mutect2, varscan2
- CACNG4 | c.84C>T p.I28= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV50925575, COSV50928359; called by muse, mutect2, varscan2
- CPN2 | c.231G>A p.K77= | Silent (SNP) | VAF 57/321 reads (18%) | catalogued as rs1318595560, COSV60471178; called by muse, mutect2, varscan2
- DPY19L1 | c.732C>T p.L244= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV60582013; called by muse, mutect2, varscan2
- FBXL7 | c.705C>A p.S235= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as COSV100309016, COSV61650030; called by muse, mutect2, varscan2
- FRMPD2 | c.1143C>G p.T381= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV100563899, COSV59721419; called by muse, mutect2, varscan2
- FYCO1 | c.1564C>T p.L522= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as COSV56118198; called by muse, varscan2
- GATAD2A | c.1473C>T p.T491= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs766602148, COSV99389423; called by muse, mutect2
- GPC6 | c.1428C>T p.N476= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs146868653; called by muse, mutect2, varscan2
- ITPR2 | c.3258G>A p.Q1086= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV67273601; called by muse, mutect2, varscan2
- LPXN | c.642C>T p.C214= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as rs763418056, COSV67717190; called by muse, mutect2, varscan2
- MTBP | c.2562C>T p.F854= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV59965040; called by muse, mutect2, varscan2
- MUC17 | c.11103C>G p.V3701= | Silent (SNP) | VAF 105/201 reads (52%) | catalogued as COSV60297422; called by muse, mutect2, varscan2
- OR2J2 | c.753C>G p.L251= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV65848235; called by muse, mutect2, varscan2
- OR9K2 | c.576T>G p.S192= (on ENST00000305377; = p.S170= on NM_001005243.1) | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as COSV59531612, COSV59532766; called by muse, mutect2, varscan2
- PLEC | c.960C>T p.F320= (on ENST00000322810 / NM_201380.4; = p.F210= on NM_000445.5) | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV59670627; called by muse, mutect2, varscan2
- PLEKHM1 | c.2802G>T p.L934= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV101378879; called by muse, mutect2
- PREX2 | c.4578C>T p.I1526= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55789251; called by muse, mutect2, varscan2
- ROPN1L | c.48C>T p.P16= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV99928787; called by muse, mutect2, varscan2
- SH3GLB2 | c.69G>T p.T23= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs751596186, COSV100999400; called by muse, mutect2, varscan2
- SLC25A23 | c.525C>T p.F175= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV51194387; called by muse, mutect2, varscan2
- SMOC2 | c.954C>T p.D318= (on ENST00000356284 / NM_001166412.2; = p.D329= on NM_022138.3) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs140169041, COSV62441702; called by muse, mutect2, varscan2
- SPEN | c.6012G>A p.P2004= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs146430628; called by muse, mutect2, varscan2
- STIP1 | c.1116G>A p.Q372= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV59440192; called by muse, mutect2, varscan2
- SULF1 | c.1539C>G p.A513= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV52688489; called by muse, mutect2, varscan2
- TRIM51 | c.667A>C p.R223= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV55269175; called by muse, mutect2, varscan2
- TRMT6 | c.1269C>T p.L423= | Silent (SNP) | VAF 148/371 reads (40%) | catalogued as COSV52544673; called by muse, mutect2, varscan2
- TUBB4B | c.1284C>A p.A428= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as COSV61118298; called by muse, mutect2, varscan2
- UBE2J1 | c.177C>T p.H59= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs754093091, COSV70561997; called by muse, mutect2, varscan2
- NACA | c.71-3505C>T | Intron (SNP) | VAF 79/168 reads (47%) | catalogued as rs1193352834, COSV100771670; called by muse, mutect2, varscan2
- TFPI | c.628+5435C>T | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV51904109; called by muse, mutect2, varscan2
